Gene-level copy-number profile of tumor specimen MP2PRT-PAPIPG-TMP1-A from MP2PRT case MP2PRT-PAPIPG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,576 days).
Specimen MP2PRT-PAPIPG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0441592d-a3b2-44e8-8e9e-da3000c0033f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPIPG-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/456fbd1f-9e19-465d-9159-a28caf8cc494

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 651; copy number 2: 41,708; copy number 3: 14,585; copy number 4: 1,823; copy number 5: 136.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 136 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:71,665,148–80,179,839, 135 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:80,161,752–80,162,413, 1 gene, copy number 5 (within-gene range 4–5): AC139100.2.

Autosomal genes at a single copy (total copy number 1): 139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
